CCDI case PBCCSA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS.
https://portal.gdc.cancer.gov/cases/02f47da4-e0b8-4ad5-9ac1-644545866006

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.8 years (308 days).

Biospecimens (3 samples)
- Sample 0DOV8M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOV92: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DOV9R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
